Somatic mutation profile of tumor specimen C3L-01459-01 (aliquot CPT0085630009) from CPTAC case C3L-01459, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 68.6 years (25,061 days).
Specimen C3L-01459-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44a2c2c8-5896-4dd3-bf43-5f1ea3671c2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01459-31 (Blood Derived Normal), aliquot CPT0086590002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/335952e8-501d-40e5-9059-7f9740a3a5fd

The open-access MAF lists 66 somatic variants for this specimen: 52 protein-altering or splice-affecting, 7 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 7, Frame Shift Del 6, Nonsense Mutation 3, 3'UTR 2, Intron 2, Frame Shift Ins 1, 5'UTR 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.449del p.N150Ifs*9 | Frame Shift Del (DEL) | VAF 50/452 reads (11%) | catalogued as rs794727253; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCC3 | c.469C>A p.L157I | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs1453491308; called by muse, mutect2
- C2orf78 | c.1169T>C p.V390A | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs1029138082; called by muse, mutect2, varscan2
- DNAH1 | c.5259C>G p.F1753L | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV70229410; called by muse, mutect2, varscan2
- KIAA0586 | c.4427C>A p.P1476Q (on ENST00000619416 / NM_001244190.2; = p.P1415Q on NM_014749.5) | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.106); catalogued as rs370303493; called by muse, mutect2, varscan2
- KLRB1 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs753350093, COSV57590543; called by muse, mutect2, varscan2
- KRT31 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs767995536, COSV52433223; called by muse, mutect2, varscan2
- LRRN2 | c.621G>A p.M207I | Missense Mutation (SNP) | VAF 48/393 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as rs1265044228; called by muse, mutect2, varscan2
- MUC16 | c.18881C>A p.T6294K | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.01); catalogued as rs747371324; called by muse, mutect2, varscan2
- OR10H4 | c.399C>A p.Y133* | Nonsense Mutation (SNP) | VAF 28/196 reads (14%) | catalogued as COSV100437736; called by muse, mutect2, varscan2
- PBRM1 | c.1162C>G p.Q388E | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV56262154, COSV56281780; called by mutect2, varscan2
- PSD | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.67); catalogued as rs781188243, COSV50044671, COSV99192090; called by muse, mutect2, varscan2
- TCHH | c.2341C>G p.R781G | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); catalogued as COSV64276638; called by muse, mutect2, varscan2
- TLL1 | c.2147A>G p.N716S | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.913); catalogued as rs1217181817, COSV50308746; called by muse, mutect2, varscan2
- TSTD2 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 40/370 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV57845729; called by muse, mutect2, varscan2
- ADCY6 | c.1739T>C p.L580P | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.861); called by muse, mutect2
- ARPC5L | c.94G>C p.A32P | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.117); called by muse, mutect2
- CACNA1G | c.290C>T p.T97I | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2
- CEP250 | c.974A>G p.E325G | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CEP89 | c.795del p.K265Nfs*4 | Frame Shift Del (DEL) | VAF 26/185 reads (14%) | called by mutect2, pindel, varscan2
- CITED2 | c.517A>G p.S173G | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0); called by mutect2, varscan2
- CRYBG1 | c.6248C>G p.S2083C | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- DCAF16 | c.239T>G p.L80R | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.278); called by muse, mutect2
- HRNR | c.80del p.T27Sfs*2 | Frame Shift Del (DEL) | VAF 35/249 reads (14%) | called by mutect2, pindel, varscan2
- IKZF3 | c.617T>C p.F206S | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- KCNJ14 | c.1202A>T p.E401V | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.348); called by muse, mutect2
- LRRN2 | c.622A>T p.N208Y | Missense Mutation (SNP) | VAF 46/389 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MAP3K2 | c.467del p.G156Vfs*51 | Frame Shift Del (DEL) | VAF 10/75 reads (13%) | called by mutect2, pindel
- MAP3K5 | c.3905del p.N1302Ifs*16 | Frame Shift Del (DEL) | VAF 12/143 reads (8%) | called by mutect2, pindel
- MTX1 | c.315A>T p.R105S | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- MUC12 | c.8078C>T p.T2693I (on ENST00000379442; = p.T2550I on NM_001164462.1) | Missense Mutation (SNP) | VAF 109/158 reads (69%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.451); called by muse, varscan2
- MYBL1 | c.772A>G p.I258V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NFATC3 | c.659C>A p.P220H | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- PAPOLG | c.411A>C p.K137N | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- PBRM1 | c.1159dup p.Y387Lfs*5 | Frame Shift Ins (INS) | VAF 19/195 reads (10%) | called by mutect2, pindel
- PCNX4 | c.2502_2509del p.K834Nfs*28 (on ENST00000406854 / NM_001330177.2; = p.K600Nfs*28 on NM_022495.5) | Frame Shift Del (DEL) | VAF 18/146 reads (12%) | called by mutect2, pindel
- PLEKHG3 | c.3405G>C p.E1135D (on ENST00000394691; = p.E1191D on NM_001308147.2) | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PTAR1 | c.73A>G p.R25G | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- PTGER3 | c.1167A>C p.Q389H | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RCN2 | c.863T>C p.I288T | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- RGS7 | c.1275C>G p.H425Q | Missense Mutation (SNP) | VAF 15/204 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.784); called by muse, mutect2
- SLC2A3 | c.1129T>A p.F377I | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by mutect2, varscan2
- SLK | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNTN | c.322T>C p.S108P | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT deleterious, low confidence (0.04); called by muse, mutect2, varscan2
- SUPV3L1 | c.387T>G p.N129K | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP37 | c.2517A>C p.L839F | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPS13B | c.2726G>T p.W909L | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF283 | c.1216A>T p.K406* | Nonsense Mutation (SNP) | VAF 25/177 reads (14%) | called by muse, mutect2, varscan2
- ZNF609 | c.1553A>G p.H518R | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF671 | c.1241T>C p.L414P | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- ZNF729 | c.1513A>T p.R505* | Nonsense Mutation (SNP) | VAF 19/144 reads (13%) | called by muse, mutect2, varscan2
- ZNF844 | c.1555T>G p.F519V | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ASCC2 | c.591C>A p.T197= | Silent (SNP) | VAF 16/194 reads (8%) | called by muse, mutect2
- CASP5 | c.645C>T p.D215= | Silent (SNP) | VAF 20/283 reads (7%) | catalogued as COSV99507756; called by muse, mutect2
- HAP1 | c.1566T>C p.Y522= (on ENST00000310778 / NM_001367460.1; = p.Y470= on NM_177977.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- MMP10 | c.1260C>T p.G420= | Silent (SNP) | VAF 16/150 reads (11%) | catalogued as COSV54248057; called by muse, mutect2, varscan2
- PTPRD | c.5121A>G p.G1707= | Silent (SNP) | VAF 13/73 reads (18%) | called by mutect2, varscan2
- PTPRZ1 | c.4068T>G p.A1356= | Silent (SNP) | VAF 13/171 reads (8%) | called by muse, mutect2
- RAB11FIP3 | c.1305C>T p.Y435= | Silent (SNP) | VAF 16/160 reads (10%) | catalogued as rs1197154178, COSV51936640; called by muse, mutect2, varscan2
- ADAM10 | c.*8T>C | 3'UTR (SNP) | VAF 85/698 reads (12%) | called by muse, mutect2, varscan2
- ADH4 | c.-39del | 5'UTR (DEL) | VAF 18/147 reads (12%) | called by mutect2, pindel, varscan2
- CEP41 | chr7:130441210 T>C | 5'Flank (SNP) | VAF 8/69 reads (12%) | catalogued as rs886062003; called by muse, varscan2
- GUSBP3 | chr5:69635390 C>T | 3'Flank (SNP) | VAF 44/432 reads (10%) | catalogued as rs1478516848; called by muse, mutect2, varscan2
- HSPE1 | c.3+11C>T | Intron (SNP) | VAF 37/305 reads (12%) | called by muse, mutect2, varscan2
- LRATD1 | c.*698C>A | 3'UTR (SNP) | VAF 33/318 reads (10%) | called by muse, mutect2, varscan2
- ZFYVE19 | c.279+399_279+406del | Intron (DEL) | VAF 30/198 reads (15%) | called by mutect2, pindel, varscan2
